Somatic mutation profile of cancer-model specimen HCM-CSHL-0585-C06-85E (3D Organoid, passage 10; aliquot HCM-CSHL-0585-C06-85E-01D-A88G-36), derived from the primary tumor of HCMI case HCM-CSHL-0585-C06, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Mouth, NOS; Tumor grade: G2.
Specimen HCM-CSHL-0585-C06-85E: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37737a69-7b2d-45e5-8852-4396dc9917d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0585-C06-11A (Solid Tissue Normal), aliquot HCM-CSHL-0585-C06-11A-11D-A88G-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b1b271b6-441f-423f-bed5-99e7e9d99a5d

The open-access MAF lists 155 somatic variants for this specimen: 113 protein-altering or splice-affecting, 37 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 95, Silent 37, Nonsense Mutation 10, Frame Shift Del 4, Frame Shift Ins 2, 5'Flank 1, Splice Region 1, RNA 1, 5'UTR 1, 3'UTR 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP3K7 | c.1535C>T p.P512L (on ENST00000369329 / NM_145331.3; = p.P485L on NM_003188.4) | Missense Mutation (SNP) | VAF 85/256 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as rs886039230, COSV100997528; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PACS1 | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 88/274 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs398123009, CM1211547, COSV57698895; ClinVar: pathogenic; called by muse, varscan2
- RRAS2 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 73/226 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs782457908, COSV56329532; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADRA1D | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 112/284 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.037); catalogued as rs1439012272; called by muse, mutect2
- AL592490.1 | c.2821C>T p.R941* | Nonsense Mutation (SNP) | VAF 99/314 reads (32%) | catalogued as rs776228199, COSV69426284; called by muse, mutect2, varscan2
- ANKRD18B | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 131/496 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs1324940983; called by muse, mutect2, varscan2
- ANKRD62 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 150/375 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs905911647, COSV58409888; called by muse, mutect2, varscan2
- APOB | c.11607C>A p.F3869L | Missense Mutation (SNP) | VAF 145/410 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.065); catalogued as COSV51942607, COSV51954942; called by muse, varscan2
- APOB | c.11107C>T p.R3703C | Missense Mutation (SNP) | VAF 141/401 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as rs777896608, COSV51932917, COSV99266703; called by muse, mutect2, varscan2
- ASXL1 | c.1900_1922del p.E635Rfs*15 | Frame Shift Del (DEL) | VAF 124/522 reads (24%) | catalogued as rs766433101; called by mutect2, varscan2
- CACNA1C | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 136/429 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV104404676, COSV59706212; called by muse, mutect2, varscan2
- CAPN1 | c.1411C>T p.R471W | Missense Mutation (SNP) | VAF 197/570 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.848); catalogued as rs775100954; called by muse, mutect2, varscan2
- CAPRIN1 | c.2062C>T p.R688* | Nonsense Mutation (SNP) | VAF 109/283 reads (39%) | catalogued as rs747560213; called by muse, mutect2, varscan2
- CASP8 | c.698G>A p.R233Q (on ENST00000432109 / NM_033355.3; = p.R250Q on NM_001228.4) | Missense Mutation (SNP) | VAF 117/304 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.787); catalogued as rs771150445, COSV51844924; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC170 | c.520C>G p.Q174E | Missense Mutation (SNP) | VAF 112/357 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs770636230; called by muse, mutect2, varscan2
- CCDC60 | c.1232G>A p.R411H | Missense Mutation (SNP) | VAF 26/222 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); catalogued as rs376048694; called by muse, mutect2
- CD2 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 97/293 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as rs1178186242; called by muse, mutect2, varscan2
- CINP | c.122A>G p.N41S | Missense Mutation (SNP) | VAF 41/420 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.098); catalogued as rs199840100; called by muse, mutect2, varscan2
- CNN1 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 168/502 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.413); catalogued as rs745990452, COSV52947530, COSV52947556; called by muse, mutect2, varscan2
- COL3A1 | c.3100C>T p.R1034C | Missense Mutation (SNP) | VAF 128/327 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1178112512, COSV58582183; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRACD | c.2095C>G p.P699A | Missense Mutation (SNP) | VAF 49/464 reads (11%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.915); catalogued as COSV99950019; called by muse, mutect2, varscan2
- CSF3R | c.2428G>A p.D810N | Missense Mutation (SNP) | VAF 194/532 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs567871402; called by muse, mutect2, varscan2
- CSTF2 | c.958G>A p.G320S | Missense Mutation (SNP) | VAF 202/284 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100880849; called by muse, mutect2, varscan2
- CTCFL | c.1330+1G>A p.X444_splice | Splice Site (SNP) | VAF 127/301 reads (42%) | catalogued as rs1286516558; called by muse, mutect2, varscan2
- CTNND2 | c.2666G>A p.R889Q | Missense Mutation (SNP) | VAF 114/458 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs867932417, COSV58869532; called by muse, mutect2, varscan2
- DEF6 | c.1367G>A p.R456Q | Missense Mutation (SNP) | VAF 86/284 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57354190; called by muse, mutect2, varscan2
- DEPDC1B | c.1582C>T p.R528* | Nonsense Mutation (SNP) | VAF 70/286 reads (24%) | catalogued as rs575323127, COSV54009042; called by muse, mutect2, varscan2
- DGKB | c.2249C>T p.T750M | Missense Mutation (SNP) | VAF 32/272 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs752662494, COSV51769770, COSV51801261; called by muse, mutect2
- DLC1 | c.2576G>A p.S859N (on ENST00000276297 / NM_001348081.2; = p.S422N on NM_006094.5) | Missense Mutation (SNP) | VAF 218/733 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs374218921; called by muse, mutect2, varscan2
- EBF2 | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 125/575 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746363034, COSV68779176; called by muse, mutect2, varscan2
- ECEL1 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 221/555 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.197); catalogued as rs1400225709; called by muse, mutect2, varscan2
- ERVV-2 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 147/433 reads (34%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.987); catalogued as rs780761856; called by muse, mutect2, varscan2
- FSIP2 | c.14975T>C p.I4992T | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as rs995630765; called by muse, mutect2, varscan2
- GGA3 | c.1669C>T p.P557S (on ENST00000537686 / NM_138619.4; = p.P524S on NM_014001.5) | Missense Mutation (SNP) | VAF 58/579 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs773020805, COSV99822253; called by muse, mutect2, varscan2
- HRNR | c.2002G>T p.D668Y | Missense Mutation (SNP) | VAF 77/741 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as rs765957331, COSV100913936; called by muse, mutect2
- IGLV9-49 | c.119C>T p.T40I | Missense Mutation (SNP) | VAF 129/389 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.171); catalogued as rs754935335; called by muse, mutect2, varscan2
- ITPR3 | c.2212C>T p.R738C | Missense Mutation (SNP) | VAF 120/361 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs780991974, COSV65406531; called by muse, mutect2, varscan2
- JPH4 | c.1414C>T p.R472* | Nonsense Mutation (SNP) | VAF 254/674 reads (38%) | catalogued as COSV58111100; called by muse, mutect2, varscan2
- KRT15 | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 79/299 reads (26%) | catalogued as rs373600329; called by muse, mutect2, varscan2
- LGALS12 | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 192/459 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); catalogued as rs201635291; called by muse, mutect2, varscan2
- MAP3K14 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 103/314 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs768000548, COSV60922931, COSV60923658; called by muse, mutect2, varscan2
- MAP3K20 | c.1682C>G p.P561R | Missense Mutation (SNP) | VAF 106/287 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.03); catalogued as rs1463738485; called by muse, mutect2, varscan2
- MUC5AC | c.395C>A p.T132K | Missense Mutation (SNP) | VAF 92/685 reads (13%) | SIFT deleterious (0.01); catalogued as rs760860834, COSV100650648, COSV100650724; called by muse, mutect2, varscan2
- MYC | c.53C>T p.S18L (on ENST00000377970; = p.S33L on NM_002467.6) | Missense Mutation (SNP) | VAF 176/638 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs776780683, COSV52377942; called by muse, varscan2
- MYH3 | c.5369C>T p.T1790M | Missense Mutation (SNP) | VAF 151/469 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as rs765724529, COSV56861016; called by muse, mutect2, varscan2
- MYH9 | c.1916G>A p.R639Q | Missense Mutation (SNP) | VAF 427/582 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV53382974; called by muse, mutect2, varscan2
- NADSYN1 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 109/311 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs772918843, COSV59813582; called by muse, mutect2, varscan2
- NIPBL | c.4699C>G p.Q1567E | Missense Mutation (SNP) | VAF 137/468 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as COSV99239301; called by muse, mutect2, varscan2
- NPTX2 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 69/356 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1200136194; called by muse, mutect2, varscan2
- NRXN2 | c.4987C>T p.R1663C | Missense Mutation (SNP) | VAF 208/586 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755501770; called by muse, mutect2, varscan2
- PCDHGA3 | c.1513G>A p.V505I | Missense Mutation (SNP) | VAF 403/778 reads (52%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.044); catalogued as COSV53891908; called by muse, mutect2, varscan2
- PRDM13 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 272/746 reads (36%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as rs982635235; called by muse, mutect2, varscan2
- QRFPR | c.830C>G p.T277R | Missense Mutation (SNP) | VAF 42/373 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs772122934; called by muse, mutect2, varscan2
- QRICH1 | c.802G>T p.V268L | Missense Mutation (SNP) | VAF 364/649 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.793); catalogued as COSV62617748; called by muse, mutect2, varscan2
- RGL4 | c.608C>A p.S203Y | Missense Mutation (SNP) | VAF 182/488 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV51944501; called by muse, mutect2, varscan2
- RYR2 | c.1614G>A p.A538= | Splice Region (SNP) | VAF 70/210 reads (33%) | catalogued as rs566885717, COSV63688605; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SIRPD | c.503C>G p.S168W | Missense Mutation (SNP) | VAF 151/440 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs946828638, COSV67546906; called by muse, mutect2, varscan2
- SIX2 | c.491C>G p.T164S | Missense Mutation (SNP) | VAF 166/454 reads (37%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.735); catalogued as rs772796826; called by muse, mutect2, varscan2
- SZT2 | c.3689C>T p.A1230V (on ENST00000634258 / NM_001365999.1; = p.A1173V on NM_015284.4) | Missense Mutation (SNP) | VAF 224/584 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.052); catalogued as rs553638915, COSV65169454; called by muse, mutect2, varscan2
- UNC5A | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 146/624 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56171642; called by muse, mutect2, varscan2
- UNC5C | c.1148T>A p.I383N | Missense Mutation (SNP) | VAF 106/345 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV71661542; called by muse, mutect2, varscan2
- WDFY4 | c.8703G>A p.W2901* | Nonsense Mutation (SNP) | VAF 126/383 reads (33%) | catalogued as COSV99630149; called by muse, mutect2, varscan2
- XIRP2 | c.4666G>C p.E1556Q (on ENST00000628543; = p.E1731Q on NM_152381.6) | Missense Mutation (SNP) | VAF 105/319 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.444); catalogued as COSV54681374; called by muse, mutect2, varscan2
- ZNF324 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 252/662 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV52181326, COSV52182275; called by muse, mutect2, varscan2
- ADAMTS14 | c.131G>T p.C44F | Missense Mutation (SNP) | VAF 148/408 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADCY4 | c.1017C>G p.I339M | Missense Mutation (SNP) | VAF 123/346 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- AJUBA | c.789dup p.V264Cfs*42 | Frame Shift Ins (INS) | VAF 307/976 reads (31%) | called by mutect2, pindel, varscan2
- AJUBA | c.434_449del p.D145Afs*92 | Frame Shift Del (DEL) | VAF 221/694 reads (32%) | called by mutect2, pindel, varscan2
- ARHGAP10 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ARID1A | c.3718C>T p.P1240S | Missense Mutation (SNP) | VAF 169/445 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATAD2B | c.4258C>T p.L1420F | Missense Mutation (SNP) | VAF 94/270 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- ATAD2B | c.1558C>G p.Q520E | Missense Mutation (SNP) | VAF 60/192 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- BUB1B | c.504T>A p.F168L | Missense Mutation (SNP) | VAF 136/335 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- CCNB2 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 88/224 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- CHD9 | c.5941C>T p.R1981* | Nonsense Mutation (SNP) | VAF 111/337 reads (33%) | called by muse, mutect2, varscan2
- CHRNA9 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 17/254 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2
- COL24A1 | c.2933G>T p.G978V | Missense Mutation (SNP) | VAF 70/227 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CST3 | c.347A>G p.H116R | Missense Mutation (SNP) | VAF 140/385 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, varscan2
- DDX31 | c.152T>C p.V51A | Missense Mutation (SNP) | VAF 79/1046 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- DEUP1 | c.1765G>A p.E589K | Missense Mutation (SNP) | VAF 71/230 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- DIPK1B | c.956T>C p.V319A | Missense Mutation (SNP) | VAF 346/680 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- FOXD2 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 150/495 reads (30%) | called by mutect2, varscan2
- GNG14 | c.250A>T p.N84Y | Missense Mutation (SNP) | VAF 209/548 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- GSTA1 | c.410A>G p.E137G | Missense Mutation (SNP) | VAF 74/164 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HOXD11 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 130/366 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- IGLV1-40 | c.77C>A p.P26Q | Missense Mutation (SNP) | VAF 63/540 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- INTS1 | c.5975A>G p.N1992S | Missense Mutation (SNP) | VAF 232/504 reads (46%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA0100 | c.149T>C p.F50S | Missense Mutation (SNP) | VAF 121/343 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- KMT2E | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 46/207 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- LINGO3 | c.1709G>A p.R570H | Missense Mutation (SNP) | VAF 208/541 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRP1B | c.13070A>T p.E4357V | Missense Mutation (SNP) | VAF 173/432 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- LRRTM2 | c.1234C>A p.P412T | Missense Mutation (SNP) | VAF 144/625 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- NCBP3 | c.1216C>G p.L406V | Missense Mutation (SNP) | VAF 143/391 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NEK1 | c.1511G>T p.R504I | Missense Mutation (SNP) | VAF 87/249 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- OR9H1P | c.876C>A p.N292K | Missense Mutation (SNP) | VAF 12/430 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PAPPA | c.173C>G p.S58W | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.102); called by muse, varscan2
- POTEE | c.931C>G p.L311V | Missense Mutation (SNP) | VAF 119/330 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- RAG1 | c.1505C>A p.P502H | Missense Mutation (SNP) | VAF 191/483 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RAPGEF5 | c.1544dup p.L515Ffs*3 (on ENST00000401957 / NM_001367602.2; = p.L818Ffs*3 on NM_012294.5) | Frame Shift Ins (INS) | VAF 23/178 reads (13%) | called by mutect2, pindel, varscan2
- RYR1 | c.10305C>G p.F3435L | Missense Mutation (SNP) | VAF 125/369 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- SHTN1 | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 95/256 reads (37%) | called by muse, mutect2, varscan2
- SLC7A10 | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 126/376 reads (34%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.703); called by muse, varscan2
- STAB1 | c.7490del p.L2497Pfs*103 | Frame Shift Del (DEL) | VAF 506/1147 reads (44%) | called by mutect2, pindel, varscan2
- STON1-GTF2A1L | c.2170G>A p.E724K | Missense Mutation (SNP) | VAF 58/174 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- SYT9 | c.337G>C p.E113Q | Missense Mutation (SNP) | VAF 156/425 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- TBC1D10B | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 16/448 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2
- TBXT | c.595C>T p.Q199* | Nonsense Mutation (SNP) | VAF 100/302 reads (33%) | called by muse, mutect2
- TDRD1 | c.1564G>C p.E522Q | Missense Mutation (SNP) | VAF 94/294 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- TRMT1 | c.111G>A p.M37I | Missense Mutation (SNP) | VAF 220/573 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UNC5D | c.2370C>G p.F790L | Missense Mutation (SNP) | VAF 138/606 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- XIRP2 | c.3971T>A p.F1324Y (on ENST00000628543; = p.F1499Y on NM_152381.6) | Missense Mutation (SNP) | VAF 154/385 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- XYLT1 | c.886A>C p.K296Q | Missense Mutation (SNP) | VAF 117/388 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ZNF257 | c.1193del p.K398Rfs*26 | Frame Shift Del (DEL) | VAF 126/371 reads (34%) | called by mutect2, pindel, varscan2
- AC099489.1 | c.6162C>T p.D2054= | Silent (SNP) | VAF 176/431 reads (41%) | catalogued as rs753895660; called by muse, mutect2, varscan2
- ALPK2 | c.4314C>T p.D1438= | Silent (SNP) | VAF 157/425 reads (37%) | catalogued as rs543350348; called by muse, mutect2, varscan2
- AMER2 | c.738C>T p.R246= | Silent (SNP) | VAF 235/700 reads (34%) | catalogued as COSV63439853; called by muse, mutect2, varscan2
- APLP2 | c.1602C>T p.H534= | Silent (SNP) | VAF 92/290 reads (32%) | catalogued as rs117077516; called by muse, mutect2, varscan2
- ARMH1 | c.354G>A p.K118= | Silent (SNP) | VAF 104/379 reads (27%) | called by muse, mutect2, varscan2
- ARVCF | c.2844C>T p.D948= | Silent (SNP) | VAF 238/649 reads (37%) | catalogued as rs910548294; called by muse, mutect2, varscan2
- ASCC2 | c.333G>A p.E111= | Silent (SNP) | VAF 159/426 reads (37%) | called by muse, mutect2, varscan2
- BEND3 | c.2469A>C p.A823= | Silent (SNP) | VAF 108/318 reads (34%) | called by muse, mutect2, varscan2
- CAD | c.4485G>A p.G1495= | Silent (SNP) | VAF 211/560 reads (38%) | called by muse, mutect2, varscan2
- DHRS7C | c.522C>T p.I174= (on ENST00000330255 / NM_001220493.2; = p.I173= on NM_001105571.3) | Silent (SNP) | VAF 92/316 reads (29%) | catalogued as rs376096593, COSV100364640; called by muse, mutect2, varscan2
- ELAPOR2 | c.148C>T p.L50= | Silent (SNP) | VAF 219/469 reads (47%) | called by muse, mutect2, varscan2
- EXOSC1 | c.438C>T p.T146= | Silent (SNP) | VAF 167/491 reads (34%) | catalogued as rs377237874; called by muse, mutect2, varscan2
- GAK | c.2805G>T p.L935= | Silent (SNP) | VAF 257/734 reads (35%) | called by muse, mutect2, varscan2
- GCN1 | c.7494C>T p.G2498= | Silent (SNP) | VAF 202/476 reads (42%) | called by muse, mutect2, varscan2
- GSDME | c.1197C>T p.S399= | Silent (SNP) | VAF 30/147 reads (20%) | catalogued as rs778523430, COSV61653006; ClinVar: likely benign; called by muse, mutect2, varscan2
- INPP5B | c.2769C>T p.L923= (on ENST00000373023; = p.L843= on NM_005540.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 73/248 reads (29%) | catalogued as COSV65962729; called by muse, mutect2, varscan2
- LZTS1 | c.912C>T p.D304= | Silent (SNP) | VAF 240/841 reads (29%) | catalogued as rs1430325591; called by muse, mutect2, varscan2
- MYO15B | c.1671G>A p.S557= | Silent (SNP) | VAF 202/560 reads (36%) | called by muse, mutect2, varscan2
- OIT3 | c.402C>T p.T134= | Silent (SNP) | VAF 120/374 reads (32%) | called by muse, mutect2, varscan2
- OR4N2 | c.747C>T p.F249= | Silent (SNP) | VAF 34/636 reads (5%) | catalogued as COSV60051390; called by muse, mutect2
- PCDHA13 | c.1287C>T p.D429= | Silent (SNP) | VAF 52/970 reads (5%) | catalogued as COSV56505472; called by muse, mutect2
- PCDHA6 | c.2247G>A p.S749= | Silent (SNP) | VAF 201/604 reads (33%) | catalogued as COSV65343943; called by muse, mutect2, varscan2
- PLEC | c.11604C>T p.G3868= (on ENST00000322810 / NM_201380.4; = p.G3758= on NM_000445.5) | Silent (SNP) | VAF 318/1171 reads (27%) | catalogued as rs782316917; called by muse, mutect2, varscan2
- PRICKLE1 | c.429C>T p.S143= | Silent (SNP) | VAF 199/493 reads (40%) | called by muse, mutect2, varscan2
- RASGRF2 | c.132C>T p.F44= | Silent (SNP) | VAF 207/856 reads (24%) | catalogued as COSV99430133; called by muse, mutect2, varscan2
- RIN1 | c.1413G>A p.L471= | Silent (SNP) | VAF 38/1080 reads (4%) | called by muse, mutect2
- RRP12 | c.2916C>A p.V972= | Silent (SNP) | VAF 126/379 reads (33%) | called by muse, mutect2, varscan2
- SCRIB | c.1791C>T p.G597= | Silent (SNP) | VAF 309/1178 reads (26%) | catalogued as rs770599690; called by muse, mutect2, varscan2
- SLIT3 | c.4551C>T p.C1517= | Silent (SNP) | VAF 240/466 reads (52%) | catalogued as rs375394267; called by muse, mutect2, varscan2
- SPANXD | c.291G>A p.K97= | Silent (SNP) | VAF 125/173 reads (72%) | catalogued as rs782376465; called by muse, mutect2, varscan2
- TAAR6 | c.45C>T p.Y15= | Silent (SNP) | VAF 158/401 reads (39%) | catalogued as rs781438215; called by muse, mutect2, varscan2
- TACR3 | c.1248C>T p.N416= | Silent (SNP) | VAF 141/410 reads (34%) | catalogued as rs377383963, COSV100510378, COSV99072676; called by muse, mutect2, varscan2
- TCTN1 | c.756T>C p.N252= | Silent (SNP) | VAF 115/282 reads (41%) | called by muse, mutect2, varscan2
- TP53TG5 | c.825T>C p.H275= | Silent (SNP) | VAF 207/567 reads (37%) | called by muse, mutect2, varscan2
- WTIP | c.555C>T p.L185= | Silent (SNP) | VAF 75/761 reads (10%) | catalogued as rs1404865370; called by muse, mutect2
- ZMIZ2 | c.1149C>T p.S383= | Silent (SNP) | VAF 218/507 reads (43%) | catalogued as rs753993071, COSV54806278; called by muse, mutect2, varscan2
- ZPLD1 | c.402T>C p.I134= (on ENST00000466937 / NM_001329788.1; = p.I150= on NM_175056.2) | Silent (SNP) | VAF 244/466 reads (52%) | called by muse, mutect2, varscan2
- C2orf80 | c.-112G>C | 5'UTR (SNP) | VAF 141/363 reads (39%) | catalogued as rs1455182559; called by muse, mutect2, varscan2
- CCSER2 | c.*379G>A | 3'UTR (SNP) | VAF 120/388 reads (31%) | catalogued as rs1354193121; called by muse, mutect2, varscan2
- DARS-AS1 | n.890A>T | RNA (SNP) | VAF 28/348 reads (8%) | called by muse, mutect2
- LYPLAL1 | chr1:219173682 A>G | 5'Flank (SNP) | VAF 140/393 reads (36%) | called by muse, mutect2, varscan2
- NLRP7 | c.2810+2794C>T | Intron (SNP) | VAF 203/602 reads (34%) | called by muse, mutect2, varscan2
